Somatic mutation profile of tumor specimen HTMCP-03-06-02193-01A (aliquot HTMCP-03-06-02193-01A-01D-6194) from CGCI case HTMCP-03-06-02193, project CGCI-HTMCP-CC (HIV+ Tumor Molecular Characterization Project - Cervical Cancer). Sex at birth: female; Vital status: Alive; Primary diagnosis: Adenocarcinoma, NOS; Tissue or organ of origin: Cervix uteri; FIGO stage: Stage IIIA; Tumor grade: GX; Age at diagnosis: 47.9 years (17,484 days).
Specimen HTMCP-03-06-02193-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) cdf4c96d-f3fa-459d-801c-fb3e4cc5f8dd.targeted_sequencing.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen HTMCP-03-06-02193-10A (Blood Derived Normal), aliquot HTMCP-03-06-02193-10A-01D-6194; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/e3c33414-f5c5-4d90-abba-01e000b2361a

The open-access MAF lists 38 somatic variants for this specimen: 29 protein-altering or splice-affecting, 5 silent, 4 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 29, Silent 5, Intron 2, RNA 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- SMARCA2 | c.2554G>A p.E852K | Missense Mutation (SNP) | VAF 37/100 reads (37%) | SIFT deleterious (0.02); PolyPhen benign (0.298); catalogued as rs281875199, CM122566, CM1310758, COSV61809210; ClinVar: pathogenic; called by muse, mutect2, varscan2
- ADAM15 | c.460G>A p.E154K | Missense Mutation (SNP) | VAF 12/24 reads (50%) | SIFT deleterious (0); PolyPhen possibly damaging (0.852); catalogued as COSV55060488; called by muse, varscan2
- ADNP | c.2662G>A p.E888K | Missense Mutation (SNP) | VAF 83/194 reads (43%) | SIFT tolerated, low confidence (0.33); PolyPhen benign (0.003); catalogued as COSV62425267; called by muse, mutect2, varscan2
- ALS2 | c.4099G>A p.D1367N | Missense Mutation (SNP) | VAF 37/139 reads (27%) | SIFT tolerated (0.73); PolyPhen benign (0); catalogued as COSV51885874; called by muse, mutect2, varscan2
- APLP1 | c.568G>A p.G190S | Missense Mutation (SNP) | VAF 22/53 reads (42%) | SIFT tolerated (1); PolyPhen benign (0.214); catalogued as rs762548083; called by muse, mutect2, varscan2
- BNC2 | c.121C>G p.Q41E | Missense Mutation (SNP) | VAF 14/48 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen benign (0); catalogued as COSV66142615; called by muse, mutect2
- CFTR | c.358G>A p.A120T | Missense Mutation (SNP) | VAF 25/69 reads (36%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.987); catalogued as rs201958172, CM940242, COSV50051650; ClinVar: not provided / uncertain significance; called by muse, mutect2, varscan2
- CSMD1 | c.8281G>A p.V2761M (on ENST00000520002; = p.V2760M on NM_033225.6) | Missense Mutation (SNP) | VAF 23/71 reads (32%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.997); catalogued as rs753927140, COSV59279948; called by muse, mutect2, varscan2
- DNAH12 | c.3184C>T p.R1062W (on ENST00000351747; = p.R1085W on NM_001366028.2) | Missense Mutation (SNP) | VAF 42/118 reads (36%) | SIFT deleterious (0); PolyPhen probably damaging (0.983); catalogued as rs1475168009, COSV61060771; called by muse, varscan2
- MUC5B | c.12467C>T p.S4156F | Missense Mutation (SNP) | VAF 11/108 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.664); catalogued as COSV101500445; called by muse, mutect2, varscan2
- NHS | c.2162G>A p.R721H | Missense Mutation (SNP) | VAF 41/110 reads (37%) | SIFT tolerated (0.28); PolyPhen benign (0.006); catalogued as rs369653594; called by muse, mutect2, varscan2
- PPP2R2B | c.158G>A p.R53Q (on ENST00000394409; = p.R119Q on NM_181674.2) | Missense Mutation (SNP) | VAF 40/127 reads (31%) | SIFT deleterious (0.04); PolyPhen benign (0.036); catalogued as rs376773964; called by muse, mutect2, varscan2
- SDK2 | c.4183G>A p.E1395K | Missense Mutation (SNP) | VAF 15/30 reads (50%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.697); catalogued as rs1279937439; called by muse, mutect2, varscan2
- SNCAIP | c.439G>A p.D147N | Missense Mutation (SNP) | VAF 36/91 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs775708743, COSV54420188; called by muse, mutect2, varscan2
- TRIM5 | c.757G>C p.V253L | Missense Mutation (SNP) | VAF 36/110 reads (33%) | SIFT tolerated (0.13); PolyPhen benign (0.003); catalogued as COSV59902725; called by muse, mutect2
- ATP2B3 | c.3211C>T p.H1071Y | Missense Mutation (SNP) | VAF 9/34 reads (26%) | SIFT tolerated (0.28); PolyPhen benign (0.018); called by muse, mutect2, varscan2
- DOP1A | c.6828G>T p.E2276D | Missense Mutation (SNP) | VAF 18/58 reads (31%) | SIFT tolerated (0.29); PolyPhen benign (0.437); called by muse, varscan2
- GPKOW | c.298G>T p.V100L | Missense Mutation (SNP) | VAF 10/23 reads (43%) | SIFT tolerated (0.06); PolyPhen benign (0.106); called by muse, mutect2, varscan2
- MAP1A | c.6505G>A p.G2169S | Missense Mutation (SNP) | VAF 10/46 reads (22%) | SIFT deleterious, low confidence (0); PolyPhen possibly damaging (0.543); called by muse, mutect2, varscan2
- MGAM | c.3658C>A p.P1220T | Missense Mutation (SNP) | VAF 41/106 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- MUC5B | c.8210C>T p.S2737F | Missense Mutation (SNP) | VAF 28/152 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.648); called by muse, mutect2, varscan2
- MUC5B | c.8375C>T p.S2792F | Missense Mutation (SNP) | VAF 44/247 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.137); called by muse, mutect2, varscan2
- NCOA1 | c.2285C>T p.S762L | Missense Mutation (SNP) | VAF 92/294 reads (31%) | SIFT tolerated (0.12); PolyPhen benign (0.115); called by muse, mutect2, varscan2
- PARP4 | c.4856G>T p.G1619V | Missense Mutation (SNP) | VAF 37/88 reads (42%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PHF8 | c.2318C>T p.S773L (on ENST00000357988 / NM_001184896.1; = p.S737L on NM_015107.3) | Missense Mutation (SNP) | VAF 10/32 reads (31%) | SIFT tolerated (0.06); PolyPhen benign (0.186); called by muse, mutect2, varscan2
- POLG | c.1424C>T p.S475L | Missense Mutation (SNP) | VAF 39/60 reads (65%) | SIFT tolerated (0.14); PolyPhen benign (0.038); called by muse, mutect2, varscan2
- TEK | c.2643C>G p.H881Q | Missense Mutation (SNP) | VAF 76/200 reads (38%) | SIFT tolerated (0.15); PolyPhen benign (0.015); called by muse, mutect2, varscan2
- TPR | c.2524G>A p.E842K | Missense Mutation (SNP) | VAF 38/108 reads (35%) | SIFT deleterious (0.01); PolyPhen benign (0.265); called by muse, mutect2, varscan2
- USP37 | c.1559C>T p.S520L | Missense Mutation (SNP) | VAF 49/147 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); called by muse, mutect2, varscan2
- PCDHB10 | c.1224G>A p.A408= | Silent (SNP) | VAF 76/232 reads (33%) | catalogued as rs782350373; called by muse, mutect2, varscan2
- PHF8 | c.2193C>G p.L731= (on ENST00000357988 / NM_001184896.1; = p.L695= on NM_015107.3) | Silent (SNP) | VAF 37/129 reads (29%) | catalogued as rs1557099421; called by muse, varscan2
- SF3B3 | c.2925G>A p.K975= | Silent (SNP) | VAF 35/69 reads (51%) | called by muse, mutect2, varscan2
- TM7SF3 | c.879T>C p.S293= | Silent (SNP) | VAF 33/54 reads (61%) | called by muse, mutect2, varscan2
- TTN | c.46347G>A p.G15449= (on ENST00000591111; = p.G8025= on NM_003319.4) | Silent (SNP) | VAF 53/154 reads (34%) | called by muse, mutect2, varscan2
- FRG1HP | n.459+549G>C | Intron (SNP) | VAF 120/720 reads (17%) | catalogued as rs1387476572; called by muse, varscan2
- ITPRID2 | c.*54C>T | 3'UTR (SNP) | VAF 58/148 reads (39%) | called by muse, mutect2, varscan2
- PHF8 | c.2237+37C>T | Intron (SNP) | VAF 16/70 reads (23%) | called by muse, varscan2
- RNU1-1 | n.159C>T | RNA (SNP) | VAF 52/288 reads (18%) | catalogued as rs1248792409; called by muse, varscan2
